CCDI case PBCELV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/e9630042-7f41-4dd6-a933-e36dfc159d80

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation: ICD-O-3 morphology code: 9561/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.9 years (5,802 days).

Biospecimens (4 samples)
- Sample 0DQ55E: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DQKYL, 0DQKYM (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQKZI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
